TARGET case TARGET-30-PARURB — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8eea83f6-dc3b-5a4b-a482-b6e9594f226e

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 5 years; Vital status: Dead; Days to death: 724 days (2.0 years).

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 6.0 years (2,178 days); Year of diagnosis: 2008; Days to last follow up: 724 days (2.0 years); Cog neuroblastoma risk group: High Risk; Inpc grade: Undifferentiated or Poorly Differentiated; INSS stage: Stage 4; Mitosis karyorrhexis index: Low.
   Pathology details: Percent tumor nuclei: 0.
   Treatment given: Protocol identifier: ACCL05C1.
   Treatment given: Protocol identifier: ANBL0032.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (3 entries)
- Days to follow up: 365 days (1.0 years); Progression or recurrence anatomic site: Bone marrow; Days to first event: 365 days (1.0 years); First event: Progression.
- Days to follow up: 365 days (1.0 years); Progression or recurrence anatomic site: Bone, NOS.
- Days to follow up: 724 days (2.0 years); Year of follow up: 2010.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PARURB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PARURB-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 724
- Protocol: ANBL00B1, ACCL05C1, ANBL0032
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.33
- Histology: Unfavorable
- MKI: Low
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Tumor: 0
- Site of Relapse: Bone; Bone Marrow
